Somatic mutation profile of tumor specimen TARGET-10-PASXSI-09A (aliquot TARGET-10-PASXSI-09A-01D) from TARGET case TARGET-10-PASXSI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,272 days).
Specimen TARGET-10-PASXSI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7df1060b-4d46-4194-af75-a694a653e01d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASXSI-10A (Blood Derived Normal), aliquot TARGET-10-PASXSI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee255899-7ffa-4651-8aac-7af0503ee68e

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Ins 2, 3'Flank 1, Silent 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.5596G>A p.A1866T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs755581538, COSV55783393; called by muse, mutect2, varscan2
- CACNA1C | c.4472C>T p.P1491L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59731438; called by muse, mutect2, varscan2
- CRTAC1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54003360; called by muse, mutect2, varscan2
- DDX17 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV99318944; called by muse, mutect2
- ELAC2 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767473238; called by muse, mutect2
- NBR1 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV57833320; called by muse, mutect2, varscan2
- SALL1 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51759285; called by muse, mutect2
- NOTCH1 | c.4745_4746insT p.E1583Gfs*27 | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | called by mutect2, pindel*, varscan2*
- NSD2 | c.2153_2154insGGGTATT p.F718Lfs*6 | Frame Shift Ins (INS) | VAF 35/79 reads (44%) | called by mutect2, pindel, varscan2
- PTPN6 | c.897C>T p.S299= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs377270547; called by muse, mutect2, varscan2
- HSD17B1 | c.539+54G>A | Intron (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- SCUBE1 | c.*5560A>G | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- SLAMF8 | chr1:159840994 C>T | 3'Flank (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
